Surgical pathology report (de-identified scan), TCGA case TCGA-DY-A1H8, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DY-A1H8-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3 Adenocarcinoma, NOS 8140/3
Site: rectum, NOS c20.9 2/10/11
w

Tumor)

Page 1 of 2

Histology:	Adenocarcinoma		
Site from oncology	Rectum		
Description of other histology:			
Grade:	Moderately Differentiated		
Mucinous:	☐ No ☐ Yes ☐ Yes (Focal) ☐ Unknown		
Signet Ring Feature:	☐ No ☐ Yes ☐ Yes (Focal) ☐ Unknown		
Histologic Heterogeneity:	☐ No ☐ Yes ☐ Unknown		
Host Response:			
Crohn's like reaction	☐ None	☐ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☐ Expansile ☐ Invasive ☐ Expansile and Invasive ☐ Unknown		
Inflammatory Bowel Disease	☐ No ☐ Yes ☐ Unknown		
Angiolymphatic Invasion:	☐ No ☐ Yes ☐ Unknown		
Mutator Phenotype:	☐ No		

[page 2 of 2]
(Enter... Page 2 of 2)

	☐ Yes ☐ Unknown
Quality for Diagnosis:	☐ High ☐ Moderate ☐ Low
Quality of staining:	☐ High ☐ Moderate ☐ Low
Number of Slides	
Cumulative Cross Sections	
Garland Necrosis present:	☐ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	
Pathologist Comment:	

Source: NCI Genomic Data Commons file d49d5096-36e3-44ea-8bc2-2657d91636fd (TCGA-DY-A1H8.50AF37CA-825F-4A4E-AEC6-F925892DDBC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).